Somatic mutation profile of tumor specimen BA2116D (aliquot aq-BA2116D) from BEATAML1.0 case 2192, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.5 years (29,759 days).
Specimen BA2116D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fd6875e-3672-4998-82f7-160912688a50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2980D (Solid Tissue Normal), aliquot aq-BA2980D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4012bb62-e01e-40e2-8ad6-67fee07a186b

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 2, 3'UTR 2, In Frame Del 1, Intron 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.6521_6523del p.F2174del | In Frame Del (DEL) | VAF 42/51 reads (82%) | catalogued as rs587784206; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 115/216 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBLN2 | c.1942G>T p.G648C | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.502); catalogued as rs1045790018, COSV55483624; called by mutect2, varscan2
- NLRP3 | c.2932G>A p.D978N | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.097); catalogued as COSV100275358; called by muse, mutect2, varscan2
- NR1H4 | c.1276C>T p.L426F (on ENST00000551379 / NM_001206993.2; = p.L412F on NM_005123.4) | Missense Mutation (SNP) | VAF 111/228 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51849822, COSV51850320; called by muse, mutect2, varscan2
- SLC4A3 | c.1958C>T p.T653M | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs201680260; called by muse, mutect2, varscan2
- TP53 | c.617del p.L206Wfs*41 | Frame Shift Del (DEL) | VAF 96/266 reads (36%) | catalogued as COSV52853973; called by mutect2, pindel, varscan2
- XIRP1 | c.3176G>A p.R1059Q | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs142701163, COSV100453738; called by muse, mutect2, varscan2
- BAIAP3 | c.2857G>C p.A953P | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CYP2C9 | c.462G>C p.E154D | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2
- HDHD2 | c.154_158dup p.Q54Afs*6 | Frame Shift Ins (INS) | VAF 77/204 reads (38%) | called by mutect2, pindel, varscan2
- KCNH7 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- MYO15B | c.3266A>C p.D1089A | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PUM1 | c.2440T>G p.S814A | Missense Mutation (SNP) | VAF 124/242 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- REXO1 | c.3239C>T p.T1080M | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIAM1 | c.3754C>T p.Q1252* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- ZNF518B | c.3091T>A p.S1031T | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ZNF644 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ADAM2 | c.843C>A p.T281= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as rs370082987; called by muse, mutect2, varscan2
- CDC5L | c.1890A>G p.K630= | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as COSV65175703; called by muse, mutect2
- FSCN3 | c.366C>T p.D122= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as rs960337966; called by muse, mutect2, varscan2
- DDX41 | c.*970C>G | 3'UTR (SNP) | VAF 44/47 reads (94%) | called by muse, mutect2, varscan2
- DST | c.4297-3810T>A | Intron (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- TP53TG3D | c.*470A>G | 3'UTR (SNP) | VAF 49/103 reads (48%) | catalogued as rs747673420; called by muse, mutect2, varscan2
- UBE2DNL | n.456G>A | RNA (SNP) | VAF 30/31 reads (97%) | called by muse, mutect2, varscan2
